Gene-level copy-number profile of tumor specimen HCM-SANG-1094-C16-01A-01D-A80T-32 from HCMI case HCM-SANG-1094-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-1094-C16-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1970307d-e96f-4f66-a565-bc5b6a5de52b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1094-C16-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/8c10eef7-deb2-40ac-b730-9930e4e30a69

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 479; copy number 1: 16,412; copy number 2: 33,044; copy number 3: 7,146; copy number 4: 1,391; copy number 5: 164; copy number 6: 45; copy number 7: 21; copy number 8: 105; copy number 9: 5; copy number 11: 4; copy number 12: 22; copy number 14: 1; copy number 16: 16; copy number 17: 18; copy number 18: 6; copy number 19: 36; copy number 21: 1.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:73,995,193–74,709,963, 12 genes (within-gene range 0–1): VCL, AL596247.1, AP3M1, ADK, TIMM9P1, RPSAP6, RAB5CP1, AC022540.1, MRPL35P3, Y_RNA, NDUFA8P1, POLR3DP1.
- chr15:34,415,450–34,521,791, 4 genes (within-gene range 0–2): AC025678.3, HNRNPLP2, FSCN1P1, DNM1P5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 444 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:157,081,667–157,160,760, 5 genes, copy number 5: LINC00880, LINC02029, LINC00881, CCNL1, Y_RNA.
- chr3:159,902,045–161,821,908, 33 genes, copy number 8: IL12A-AS1, IL12A, LINC01100, BRD7P2, C3orf80, AC079594.1, IFT80, RPL35AP10, SMC4, MIR15B, MIR16-2, TRIM59, B3GAT3P1, RNU7-136P, KPNA4, SCARNA7, KRT8P12, RPL6P8, ARL14, SNORA72, AC069224.1, PPM1L, B3GALNT1, NMD3, AC108738.1, EEF1GP4, PSMC1P7, SPTSSB, LINC02067, AC112491.1, RPL23AP42, OTOL1, AC131211.1.
- chr3:167,065,831–173,141,235, 108 genes, copy number 6–8 (broad region; genes not listed).
- chr3:176,415,439–178,937,352, 28 genes, copy number 6–7 (within-gene range 4–7): LINC01208, RNA5SP147, LINC01209, MTND5P15, TBL1XR1, TBL1XR1-AS1, Y_RNA, RNU6-681P, LINC00501, ASS1P7, AC117465.1, LINC00578, RN7SKP52, AC026355.3, AC026355.1, AC026355.2, AC026355.4, LINC02015, AC007953.1, AC007953.2, RNU6-1120P, AC117453.1, KCNMB2, AC117457.1, LINC01014, RNA5SP148, PPIAP75, KCNMB2-AS1.
- chr15:40,569,299–40,585,751, 2 genes, copy number 6: RPUSD2, Metazoa_SRP.
- chr15:44,778,196–45,522,755, 42 genes, copy number 5 (within-gene range 1–5): AC122108.2, SORD2P, AC122108.1, Y_RNA, RNU1-119P, AC090888.3, AC090888.1, RNU6-1108P, TERB2, RNU6-1332P, AC090888.2, RNU6-966P, RNU1-78P, SORD, AC091117.2, Y_RNA, AC091117.1, DUOX2, DUOXA2, DUOXA1, DUOX1, AC051619.5, SHF, AC051619.3, AC051619.6, AC051619.7, AC051619.9, AC051619.8, H3P39, AC051619.4, SLC28A2, AC051619.1, AC051619.2, RNU6-953P, GATM, AC025580.3, SPATA5L1, C15orf48, AC025580.1, MIR147B, AC025580.2, SLC30A4.
- chr15:56,542,952–56,918,571, 5 genes, copy number 5 (within-gene range 2–5): AC090518.1, ZNF280D, Y_RNA, AC090517.4, AC090517.2.
- chr15:56,795,460–56,918,499, 1 gene, copy number 5 (within-gene range 2–5): AC090517.5.
- chr15:68,930,504–69,099,987, 7 genes, copy number 5 (within-gene range 3–5): AC027088.1, NOX5, AC027088.5, AC027088.4, AC027088.3, EWSAT1, AC027088.2.
- chr15:89,608,789–90,234,047, 32 genes, copy number 5 (within-gene range 2–5): KIF7, PLIN1, PEX11A, RPL36AP43, WDR93, AC079075.1, RNU6-132P, MESP1, MRPL15P1, MESP2, ANPEP, AP3S2, ARPIN-AP3S2, MIR5094, AC027176.2, MIR5009, RNU6-1111P, ARPIN, RNU7-111P, AC027176.1, AC027176.3, ZNF710, MIR3174, AC087284.1, ZNF710-AS1, U7, IDH2, IDH2-DT, SEMA4B, RN7SL346P, RPS12P26, CIB1.
- chr15:101,289,784–101,525,202, 1 gene, copy number 5 (within-gene range 1–5): PCSK6.
- chr15:101,334,437–101,337,428, 1 gene, copy number 5: PCSK6-AS1.
- chr18:20,946,906–23,672,748, 61 genes, copy number 5 (broad region; genes not listed).
- chr18:58,416,765–58,477,484, 5 genes, copy number 16: AC105105.2, MIR122HG, MIR122, MIR3591, AC105105.4.
- chr18:58,862,600–59,697,662, 13 genes, copy number 9–16 (within-gene range 1–16): ZNF532, RNU2-69P, OACYLP, AC040963.1, SEC11C, GRP, RAX, CPLX4, LMAN1, AC016229.2, CCBE1, AC016229.1, AC090213.1.
- chr18:62,650,308–62,650,601, 1 gene, copy number 17: RN7SL705P.
- chr18:75,070,197–79,816,529, 90 genes, copy number 11–21 (broad region; genes not listed).
- chr18:80,034,346–80,247,514, 9 genes, copy number 5: AC090360.1, RBFA, RBFADN, SLC25A6P4, ADNP2, PARD6G-AS1, PARD6G, AC139100.2, AC139100.1.

Autosomal genes at a single copy (total copy number 1): 14,019. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
